Gene-level copy-number profile of tumor specimen TCGA-BR-8286-01A from TCGA case TCGA-BR-8286, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 49.2 years (17,966 days).
Specimen TCGA-BR-8286-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.dfa50172-ccb3-4655-828c-dc26a31bec57.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8286-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c64d15f7-2d4d-44e8-9a27-258d5931297e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 6; copy number 2: 4,877; copy number 3: 18,160; copy number 4: 23,481; copy number 5: 8,946; copy number 6: 3,655; copy number 7: 243; copy number 8: 37; copy number 9: 80; copy number 10: 37; copy number 11: 18; copy number 12: 50; copy number 13: 36; copy number 14: 22; copy number 15: 38; copy number 19: 30; copy number 22: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8286-01A-12D-2338-01): tumor purity 0.54, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr4:152,536,264–152,918,463, 9 genes (within-gene range 0–3): MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1, TIGD4, ARFIP1, NSA2P6.
- chr8:49,330,210–49,554,414, 4 genes: RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1.
- chr8:63,687,179–64,369,176, 1 gene (within-gene range 0–6): LINC01414.
- chr8:64,331,927–64,462,926, 4 genes: COX6CP8, MIR124-2HG, MIR124-2, AC012535.1.
- chr8:80,967,810–81,165,266, 4 genes: PAG1, AC022778.1, AC079209.2, AC079209.1.
- chr8:83,912,713–84,921,844, 4 genes (within-gene range 0–6): AC015522.1, TPM3P3, AC012400.1, RALYL.
- chr8:89,243,401–89,243,793, 1 gene: RPSAP74.
- chr8:90,621,995–90,791,632, 1 gene (within-gene range 0–5): TMEM64.
- chr8:90,701,082–91,219,236, 11 genes (within-gene range 0–2): AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP.
- chr8:95,505,406–96,160,806, 8 genes (within-gene range 0–2): AC083836.1, RNU6-690P, SRSF3P2, AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6.
- chr8:101,411,873–101,669,726, 5 genes (within-gene range 0–5): AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:109,362,461–110,349,607, 12 genes: PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1.
- chr8:110,766,863–112,148,825, 11 genes (within-gene range 0–2): AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, RNU4-37P.
- chr8:117,128,455–117,164,255, 2 genes: AC027419.2, RN7SL826P.
- chr8:122,414,332–122,781,071, 8 genes (within-gene range 0–5): SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2.
- chr8:136,237,236–136,295,232, 1 gene (within-gene range 0–3): AC023781.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 315 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:45,035,199–45,895,970, 6 genes, copy number 9: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:43,995,723–44,074,652, 2 genes, copy number 9 (within-gene range 6–9): AL109615.3, C6orf223.
- chr6:55,680,642–56,954,649, 9 genes, copy number 9 (within-gene range 6–9): AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1.
- chr8:15,896,267–16,567,490, 6 genes, copy number 9 (within-gene range 5–9): AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2.
- chr8:60,965,802–61,944,180, 14 genes, copy number 9 (within-gene range 6–9): AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3.
- chr8:71,675,300–72,251,565, 9 genes, copy number 9: AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1.
- chr8:72,537,225–72,938,349, 1 gene, copy number 9 (within-gene range 3–9): KCNB2.
- chr8:72,660,584–74,208,536, 41 genes, copy number 9–13: AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1.
- chr8:126,474,189–127,742,951, 21 genes, copy number 10: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 10: MIR1204.
- chr8:134,477,788–134,881,899, 15 genes, copy number 10 (within-gene range 5–10): ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1.
- chr18:11,326,270–14,132,490, 101 genes, copy number 9–19 (broad region; genes not listed).
- chr18:20,946,906–23,026,488, 50 genes, copy number 12: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:23,506,184–24,135,829, 13 genes, copy number 13 (within-gene range 8–13): NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4.
- chr18:25,818,234–27,190,698, 25 genes, copy number 14–22 (within-gene range 3–22): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4.
- chr18:26,952,201–26,952,558, 1 gene, copy number 14: ATP6V1E1P2.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
